Surgical pathology report (de-identified scan), TCGA case TCGA-61-1919, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1919-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

A) OMENTUM:

- METASTATIC SEROUS ADENOCARCINOMA

RIGHT ADNEXA:

- MODERATELY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA OF RIGHT OVARY WITH EXTENSION TO RIGHT PERITUBAL TISSUE

C) LEFT ADNEXA:

- MODERATELY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA OF LEFT OVARY WITH EXTENSION TO LEFT PERITUBAL TISSUE, STATUS POST TUBAL LIGATION

D) BLADDER REFLECTION:

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

E) UTERUS WITHOUT ADNEXA, 85 GRAMS:

- CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA

- INACTIVE ENDOMETRIUM

- LEIOMYOMAS, UP TO 0.7 CM

- METASTATIC PAPILLARY ADENOCARCINOMA INVOLVING SEROSAL SURFACE

F) SIGMOID NODULE X3:

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

G-J) RIGHT PELVIC SIDEWALL, CUL-DE-SAC TUMOR, SURFACE OF SIGMOID AND CUL-DE-SAC MASS:

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

Source: NCI Genomic Data Commons file 077f8168-553f-40a5-870a-4e324f9bd5f0 (TCGA-61-1919.240A49A3-B611-4949-B3B9-3799D8C0DC46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).